Somatic mutation profile of tumor specimen MMRF_1792_1_BM_CD138pos (aliquot MMRF_1792_1_BM_CD138pos_T1_KBS5U_K11349) from MMRF case MMRF_1792, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 47.7 years (17,409 days).
Specimen MMRF_1792_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f324ac60-eee4-4a1d-8c3d-d145876af2d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1792_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1792_1_PB_Whole_C2_KBS5U_K11350; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e030e60-ab82-4df7-b985-607e92b440a4

The open-access MAF lists 98 somatic variants for this specimen: 46 protein-altering or splice-affecting, 17 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 17, 3'UTR 15, Intron 11, 5'UTR 5, Splice Site 3, Frame Shift Del 2, In Frame Del 2, RNA 2, 3'Flank 1, Nonsense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/192 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.696); catalogued as rs730880154, CM1212403, COSV62520732, COSV62522404; ClinVar: uncertain significance / likely pathogenic; called by muse, varscan2
- ARFGEF3 | c.5583C>G p.D1861E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); catalogued as COSV52472615; called by muse, mutect2
- CCDC102B | c.1199T>G p.L400* | Nonsense Mutation (SNP) | VAF 61/135 reads (45%) | catalogued as rs1210732696; called by muse, mutect2, varscan2
- EYS | c.6958_6960del p.F2320del | In Frame Del (DEL) | VAF 42/100 reads (42%) | catalogued as rs1182896761; called by pindel, varscan2
- FAM216B | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs745910414; called by muse, mutect2, varscan2
- FFAR1 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50070866; called by muse, mutect2, varscan2
- FPR1 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.227); catalogued as rs146075164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs369201986; called by muse, varscan2
- IGHV2-70 | c.118A>C p.T40P | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553609563; called by muse, varscan2
- IGHV5-51 | c.218G>C p.G73A | Missense Mutation (SNP) | VAF 76/161 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs146016582; called by muse, mutect2, varscan2
- IGLV4-60 | c.236A>C p.K79T | Missense Mutation (SNP) | VAF 75/166 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.291); catalogued as rs182062284, COSV66503859; called by muse, mutect2, varscan2
- MTTP | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs201464944; called by muse, mutect2, varscan2
- MUC16 | c.32891C>T p.S10964L | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.327); catalogued as COSV67468333; called by muse, mutect2
- NCLN | c.800+1G>A p.X267_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as rs1406974470, COSV55743188; called by muse, mutect2, varscan2
- PHF21B | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.029); catalogued as rs1197836173, COSV57558304; called by muse, mutect2, varscan2
- PPFIA4 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as rs549829669; called by muse, mutect2, varscan2
- RCOR2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as COSV56850314; called by muse, mutect2, varscan2
- SLC44A5 | c.1480G>T p.D494Y | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV63769674; called by muse, mutect2
- SLC6A16 | c.1618+2T>C p.X540_splice | Splice Site (SNP) | VAF 41/66 reads (62%) | catalogued as rs1172716250; called by muse, mutect2, varscan2
- TBC1D1 | c.2674G>A p.G892S | Missense Mutation (SNP) | VAF 61/119 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99790628; called by muse, mutect2, varscan2
- TPPP | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187324219; called by muse, mutect2
- TRAPPC8 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs751961592; called by muse, mutect2, varscan2
- VPS16 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs558893855, COSV66792589; called by muse, varscan2
- BEND5 | c.1109-1G>T p.X370_splice | Splice Site (SNP) | VAF 16/37 reads (43%) | called by mutect2, varscan2
- BHLHE41 | c.1280_1285del p.G427_A428del | In Frame Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- BRD3 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CSMD3 | c.9055T>G p.Y3019D (on ENST00000297405 / NM_001363185.1; = p.Y2850D on NM_052900.3) | Missense Mutation (SNP) | VAF 64/66 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX6 | c.1267G>A p.G423R | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEPDC5 | c.3229C>G p.L1077V (on ENST00000400246; = p.L1146V on NM_014662.5) | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- DNAAF4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- EFHB | c.1862A>G p.E621G | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EFNB1 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- FKBP1C | c.236C>G p.P79R | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FLNA | c.6475C>A p.H2159N (on ENST00000369850 / NM_001110556.2; = p.H2151N on NM_001456.3) | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GEN1 | c.1731_1746del p.S578Yfs*3 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | called by mutect2, pindel, varscan2
- IER3 | c.46G>C p.A16P | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- KMT2E | c.4327_4340del p.P1443Rfs*88 | Frame Shift Del (DEL) | VAF 104/374 reads (28%) | called by mutect2, varscan2
- MYH2 | c.1580T>C p.I527T | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PDS5A | c.2774G>A p.C925Y | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PITX2 | c.794C>T p.A265V (on ENST00000354925 / NM_001204397.1; = p.A272V on NM_000325.6) | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- RPGR | c.470A>G p.E157G | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.336); called by muse, mutect2
- SRPK1 | c.794A>C p.K265T | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- TCIM | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 130/143 reads (91%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIMP2 | c.656A>T p.D219V | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZNF281 | c.865T>C p.F289L | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- AFG1L | c.612C>T p.S204= | Silent (SNP) | VAF 57/63 reads (90%) | catalogued as rs752068948; called by muse, mutect2, varscan2
- CBFA2T3 | c.85C>T p.L29= | Silent (SNP) | VAF 26/29 reads (90%) | called by muse, mutect2, varscan2
- CELSR1 | c.759G>A p.A253= | Silent (SNP) | VAF 42/121 reads (35%) | called by muse, mutect2, varscan2
- DDR1 | c.2082C>T p.D694= (on ENST00000324771; = p.D657= on NM_001954.4) | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs199585201; called by muse, mutect2, varscan2
- GPR12 | c.351C>T p.I117= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs768485819; called by muse, mutect2, varscan2
- IGHV3-33 | c.66G>A p.Q22= | Silent (SNP) | VAF 48/78 reads (62%) | catalogued as rs763028332; called by muse, varscan2
- IGLV3-1 | c.207T>C p.D69= | Silent (SNP) | VAF 57/60 reads (95%) | catalogued as rs376313046; called by muse, mutect2, varscan2
- KCNK18 | c.570G>A p.P190= | Silent (SNP) | VAF 38/106 reads (36%) | catalogued as rs752333582, COSV57970562; called by muse, mutect2, varscan2
- KMT2B | c.7572C>T p.F2524= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs1443615335; called by muse, mutect2, varscan2
- MAGEL2 | c.2610G>A p.E870= | Silent (SNP) | VAF 89/202 reads (44%) | catalogued as rs776000743; called by muse, mutect2, varscan2
- NEK8 | c.444C>T p.F148= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as rs776495618, COSV52048562; called by muse, mutect2, varscan2
- PGK1 | c.60T>C p.V20= | Silent (SNP) | VAF 33/66 reads (50%) | called by muse, mutect2, varscan2
- ROBO2 | c.135C>T p.G45= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs764373066, COSV59924953; called by muse, mutect2, varscan2
- STON2 | c.1071G>A p.T357= (on ENST00000649389 / NM_001366849.2; = p.T300= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs748540562, COSV50842328; called by muse, mutect2, varscan2
- TOX2 | c.561G>A p.S187= (on ENST00000358131 / NM_001098798.2; = p.S136= on NM_032883.3) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs144868923; called by muse, mutect2, varscan2
- TSPAN10 | c.183C>T p.H61= (on ENST00000574882 / NM_001290212.1; = p.H23= on NM_031945.4) | Silent (SNP) | VAF 31/66 reads (47%) | called by muse, mutect2, varscan2
- UMOD | c.258G>A p.T86= | Silent (SNP) | VAF 29/83 reads (35%) | called by muse, mutect2, varscan2
- ACADM | c.-30A>T | 5'UTR (SNP) | VAF 50/99 reads (51%) | called by muse, mutect2, varscan2
- AOC1 | c.-13C>T | 5'UTR (SNP) | VAF 26/275 reads (9%) | catalogued as rs746231288; called by muse, mutect2
- BMP6 | c.*1281G>A | 3'UTR (SNP) | VAF 57/170 reads (34%) | called by muse, mutect2, varscan2
- CD200 | chr3:112362264 del TAAC | 3'Flank (DEL) | VAF 40/84 reads (48%) | called by mutect2, varscan2
- CRBN | c.688-109A>C | Intron (SNP) | VAF 12/41 reads (29%) | called by muse, mutect2
- EBF1 | c.*2479del | 3'UTR (DEL) | VAF 22/88 reads (25%) | catalogued as rs763193534; called by mutect2, varscan2
- EDN3 | c.*946G>A | 3'UTR (SNP) | VAF 36/79 reads (46%) | catalogued as rs929023512; called by muse, mutect2, varscan2
- EEPD1 | c.*973C>T | 3'UTR (SNP) | VAF 34/143 reads (24%) | catalogued as rs1203261491; called by muse, mutect2, varscan2
- FAM122A | c.*275C>T | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- FAM199X | c.*5745C>A | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- HSPG2 | c.2617+81C>A | Intron (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- HUWE1 | c.*459C>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as rs1306714040, COSV99470743; called by muse, mutect2
- ICE2 | c.-190T>G | 5'UTR (SNP) | VAF 77/155 reads (50%) | catalogued as rs913984228; called by muse, mutect2, varscan2
- IFT81 | c.1188+5225A>T | Intron (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- LXN | c.*166A>T | 3'UTR (SNP) | VAF 116/235 reads (49%) | called by muse, mutect2, varscan2
- MARCHF4 | c.*948C>T | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- MGAT4A | c.-310A>C | 5'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- MIR134 | n.35A>G | RNA (SNP) | VAF 52/123 reads (42%) | catalogued as rs1239349376; called by muse, mutect2, varscan2
- MIR5195 | n.88G>C | RNA (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*2028G>A | 3'UTR (SNP) | VAF 40/164 reads (24%) | catalogued as rs1368207494; called by muse, mutect2, varscan2
- NRIP1 | c.*2387C>T | 3'UTR (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- PCDH9 | c.*325T>C | 3'UTR (SNP) | VAF 30/80 reads (38%) | called by muse, mutect2, varscan2
- POLD4 | c.98-29C>T | Intron (SNP) | VAF 148/222 reads (67%) | catalogued as rs562488135, COSV56745225; called by muse, varscan2
- POLD4 | c.98-30C>T | Intron (SNP) | VAF 148/224 reads (66%) | catalogued as rs529893518; called by muse, varscan2
- PTPN12 | c.696-2338C>A | Intron (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- SCAMP4 | c.*703dup | 3'UTR (INS) | VAF 60/124 reads (48%) | called by mutect2, pindel, varscan2
- SEPTIN1 | c.235+31G>C | Intron (SNP) | VAF 91/198 reads (46%) | called by muse, mutect2, varscan2
- SKIL | c.-275C>A | 5'UTR (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- SMARCD2 | c.724-41A>C | Intron (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2
- TMEM134 | c.239+92C>G | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TMSB4X | chrX:12975365 G>A | 5'Flank (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- UROS | c.*15G>T | 3'UTR (SNP) | VAF 10/21 reads (48%) | catalogued as rs376381784; called by muse, mutect2, varscan2
- XKR4 | c.*909G>A | 3'UTR (SNP) | VAF 36/88 reads (41%) | catalogued as rs887971327, COSV59325812; called by muse, mutect2, varscan2
- ZNF780A | c.-46+777dup | Intron (INS) | VAF 50/206 reads (24%) | called by mutect2, pindel, varscan2
- ZNF783 | c.802+3767G>A | Intron (SNP) | VAF 18/63 reads (29%) | catalogued as rs539045489, COSV100954211; called by muse, mutect2, varscan2
